Somatic mutation profile of tumor specimen C3N-01525-01 (aliquot CPT0095870053) from CPTAC case C3N-01525, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01525-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6971b0e4-98b1-415d-9d5b-6b884d55b83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01525-31 (Blood Derived Normal), aliquot CPT0095910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4cd1d92-0f01-4cd1-af6d-1c42ecb6e3b7

The open-access MAF lists 95 somatic variants for this specimen: 69 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Frame Shift Del 5, Intron 5, Nonsense Mutation 4, Frame Shift Ins 2, RNA 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 59/217 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.13489C>T p.R4497C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121918600, CM010137; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1173154389; called by muse, mutect2, varscan2
- ARHGEF10L | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355345589; called by muse, mutect2, varscan2
- ARID3B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs753085247; called by muse, mutect2
- CAMTA1 | c.3553A>G p.S1185G | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs954409338; called by muse, mutect2, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2, varscan2
- EPHB6 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 94/526 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs201556658, COSV63892635; called by muse, mutect2, varscan2
- GRIA4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs151104343; called by muse, mutect2, varscan2
- HEPACAM | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751732183, COSV53430381; called by muse, mutect2, varscan2
- HRNR | c.8408G>A p.S2803N | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs552697734; called by muse, mutect2, varscan2
- HSF4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50456664; called by muse, mutect2, varscan2
- JAG1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs766370717; called by muse, mutect2, varscan2
- KANSL1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376632173; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.9572T>G p.L3191R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52661427; called by muse, mutect2, varscan2
- KIAA2026 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 45/209 reads (22%) | catalogued as rs1228518521; called by muse, mutect2, varscan2
- LGI2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs139692298, COSV66123183; called by muse, mutect2, varscan2
- MAMLD1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs1005490291; called by muse, mutect2, varscan2
- MAP1S | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749473307; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- NICN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748614806, COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NKTR | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as rs1479671676; called by muse, mutect2, varscan2
- NLRP4 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs907483906, COSV56708637, COSV56710687; called by muse, mutect2, varscan2
- NOS3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as rs767108240; called by muse, mutect2, varscan2
- NR5A1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752292248, COSV65295683; called by muse, mutect2, varscan2
- OR10A7 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58278864; called by muse, mutect2, varscan2
- OR8D1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs562758196, COSV63441771; called by muse, mutect2, varscan2
- PAX1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68271303; called by muse, mutect2, varscan2
- PCSK2 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920293680, COSV52738706, COSV52741396; called by muse, varscan2
- PIK3R1 | c.1685G>C p.R562P (on ENST00000521381 / NM_181523.3; = p.R292P on NM_181504.4) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57124822; called by muse, mutect2, varscan2
- PRMT8 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs747021868; called by muse, mutect2, varscan2
- PSMB9 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as rs747761347; called by muse, mutect2
- ROPN1L | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1190893461; called by muse, mutect2, varscan2
- RYR1 | c.9560G>A p.R3187Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1171145743; called by muse, mutect2, varscan2
- SNX25 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.583); catalogued as rs1287699165; called by muse, mutect2, varscan2
- SRC | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1479989919; called by muse, mutect2, varscan2
- STARD6 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs145044397, COSV104410849; called by muse, mutect2, varscan2
- STXBP5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs571215145, COSV99470220; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755371712, COSV51513640; called by muse, mutect2, varscan2
- ARID1A | c.5465del p.P1822Hfs*61 | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | called by mutect2, pindel, varscan2
- ARID5B | c.1431_1434del p.L478* | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- ASH1L | c.3679T>A p.F1227I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- B4GALT1 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- CHPF | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DDB1 | c.3049C>A p.L1017M | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ERO1B | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.9247G>T p.V3083F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPH3 | c.58_61dup p.R21Pfs*68 | Frame Shift Ins (INS) | VAF 13/110 reads (12%) | called by mutect2, pindel, varscan2
- HSPA8 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KCNA7 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 99/433 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KCNH3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KMT2E | c.4373C>T p.T1458I | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MX1 | c.1951_1952del p.T651Afs*20 | Frame Shift Del (DEL) | VAF 32/179 reads (18%) | called by mutect2, pindel, varscan2
- MYO10 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- OTP | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PLSCR5 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- SBF2 | c.1860+7del | Splice Region (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- SLC25A51 | c.163del p.L55Sfs*18 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAT5A | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIM | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP36L2 | c.548dup p.R184Afs*290 | Frame Shift Ins (INS) | VAF 126/631 reads (20%) | called by mutect2, pindel, varscan2
- ZIC3 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 29/239 reads (12%) | called by muse, mutect2, varscan2
- ZNF331 | c.1172_1178del p.A391Vfs*7 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | called by mutect2, pindel, varscan2
- ZNF624 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2
- ZNF865 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- BMP2 | c.264T>G p.G88= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- EPHA2 | c.1191G>T p.V397= | Silent (SNP) | VAF 91/390 reads (23%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2607G>A p.P869= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs1451679884; called by muse, mutect2, varscan2
- GALNT3 | c.588A>G p.E196= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- HDAC4 | c.882C>T p.S294= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as rs911608166, COSV100612898; called by muse, mutect2, varscan2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- KLHL33 | c.255T>C p.P85= | Silent (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- MAP1A | c.3774C>T p.P1258= | Silent (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- MICAL1 | c.2658C>T p.D886= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- MTUS2 | c.2013G>A p.P671= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs1424838911, COSV70916627; called by muse, mutect2, varscan2
- NUBP2 | c.405G>A p.P135= | Silent (SNP) | VAF 83/322 reads (26%) | catalogued as rs144072283; called by muse, mutect2, varscan2
- OTC | c.39T>C p.A13= | Silent (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 58/305 reads (19%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PCNX3 | c.1473G>A p.T491= | Silent (SNP) | VAF 78/406 reads (19%) | catalogued as rs887263138; called by muse, mutect2, varscan2
- QPCTL | c.1011C>T p.P337= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs777466140; called by muse, mutect2, varscan2
- SYCP2L | c.111T>C p.D37= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.786C>T p.A262= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- ELK1 | c.-84G>A | 5'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- FAM27E5 | n.177C>T | RNA (SNP) | VAF 30/181 reads (17%) | catalogued as rs771362103; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46044G>A | Intron (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- MMAB | c.*790G>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- RBMX2 | c.173+10C>A | Intron (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- STRA6 | c.597+20G>A | Intron (SNP) | VAF 59/308 reads (19%) | catalogued as rs1246268008; called by muse, mutect2, varscan2
- TLX1NB | n.1490G>A | RNA (SNP) | VAF 8/86 reads (9%) | catalogued as rs1045374243; called by muse, mutect2
- TMX2 | c.250+19T>G | Intron (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- YARS1 | c.58-35C>G | Intron (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
